Somatic mutation profile of tumor specimen TARGET-10-PAREST-09A (aliquot TARGET-10-PAREST-09A-01D) from TARGET case TARGET-10-PAREST, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,371 days).
Specimen TARGET-10-PAREST-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e099922-447b-49a8-85eb-c6b1b2b970d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAREST-10A (Blood Derived Normal), aliquot TARGET-10-PAREST-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f006c5d9-7a78-4ddd-91f5-f9000f004461

The open-access MAF lists 16 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 4, Silent 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 24/67 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ELAVL4 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.895); catalogued as rs377132231, COSV63919560; called by muse, mutect2, varscan2
- HIPK2 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs747709692, COSV61225839; called by muse, mutect2
- SCN1A | c.1679G>A p.R560H | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.087); catalogued as rs746769373; called by muse, mutect2, varscan2
- GRIN2A | c.1124T>C p.V375A | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- KIF2B | c.1491C>A p.S497R | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP1B | c.9038A>T p.E3013V | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- MAP4K5 | c.557T>C p.V186A | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- THAP3 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- NUPR1 | c.162C>G p.T54= | Silent (SNP) | VAF 43/111 reads (39%) | called by muse, mutect2, varscan2
- SLC35C1 | c.663G>A p.P221= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as rs111773874; ClinVar: likely benign / uncertain significance; called by mutect2, varscan2
- ATL2 | c.1633-58A>G | Intron (SNP) | VAF 29/50 reads (58%) | catalogued as rs776636679; called by muse, mutect2, varscan2
- EPS8L2 | c.896-16G>A | Intron (SNP) | VAF 6/16 reads (38%) | catalogued as rs1200879468; called by muse, mutect2, varscan2
- GNAZ | c.-31G>A | 5'UTR (SNP) | VAF 7/20 reads (35%) | called by muse, varscan2
- PARVA | c.400+299C>T | Intron (SNP) | VAF 12/28 reads (43%) | catalogued as rs944412021; called by muse, mutect2, varscan2
- XBP1 | c.454-24_454-9del | Intron (DEL) | VAF 10/32 reads (31%) | called by mutect2, pindel, varscan2
